Somatic mutation profile of tumor specimen MMRF_2680_1_BM_CD138pos (aliquot MMRF_2680_1_BM_CD138pos_T1_KHS5U_L13800) from MMRF case MMRF_2680, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.7 years (23,614 days).
Specimen MMRF_2680_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1da69bba-942e-4aeb-984d-e23552871554.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2680_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2680_1_PB_WBC_C3_KHS5U_L13801; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7382d8b5-e785-473b-a851-b548c921a569

The open-access MAF lists 177 somatic variants for this specimen: 68 protein-altering or splice-affecting, 27 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, 3'UTR 47, Silent 27, 5'UTR 13, Intron 12, RNA 6, Splice Site 2, Frame Shift Del 2, 5'Flank 2, 3'Flank 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 208/466 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as rs886039303, CM134717, COSV56517476; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLDC | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 103/580 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121964980, CM051081; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs766460335, COSV101186604; called by muse, mutect2, varscan2
- ADARB2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1035494228, COSV67216137; called by muse, mutect2, varscan2
- CAMSAP2 | c.2020C>T p.P674S (on ENST00000236925 / NM_001297707.2; = p.P663S on NM_203459.3) | Missense Mutation (SNP) | VAF 35/604 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866124359, COSV52672835; called by muse, mutect2
- CHD6 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 148/336 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778459269, COSV58554448; called by muse, varscan2
- COCH | c.1266G>A p.M422I (on ENST00000216361 / NM_001347720.1; = p.M357I on NM_004086.3) | Missense Mutation (SNP) | VAF 28/613 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV99363364; called by muse, mutect2
- COL12A1 | c.5858G>A p.R1953H | Missense Mutation (SNP) | VAF 125/282 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs367908043; called by muse, mutect2, varscan2
- CUL2 | c.875del p.N292Mfs*20 | Frame Shift Del (DEL) | VAF 40/89 reads (45%) | catalogued as rs748548689; called by mutect2, varscan2
- DUSP2 | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV56619478; called by muse, mutect2, varscan2
- FBN2 | c.6800G>A p.R2267H | Missense Mutation (SNP) | VAF 61/369 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs868504219, COSV52531968; called by muse, mutect2, varscan2
- FBXO2 | c.530G>C p.R177P | Missense Mutation (SNP) | VAF 143/304 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.975); catalogued as rs759584337; called by muse, mutect2, varscan2
- FSHR | c.676T>G p.S226A | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58634926; called by muse, mutect2, varscan2
- FXYD2 | c.65-4G>A | Splice Region (SNP) | VAF 35/542 reads (6%) | catalogued as rs866875683; ClinVar: uncertain significance; called by muse, mutect2
- GPR148 | c.923T>C p.L308P | Missense Mutation (SNP) | VAF 60/652 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV59308256; called by muse, mutect2
- GPSM1 | c.657C>G p.H219Q | Missense Mutation (SNP) | VAF 65/619 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.194); catalogued as rs1273877864; called by muse, mutect2, varscan2
- HMCN1 | c.106C>G p.P36A | Missense Mutation (SNP) | VAF 10/341 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV54947945; called by muse, mutect2
- IGHV2-70 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 179/394 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs370734838; called by muse, varscan2
- IGHV2-70 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 180/404 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557960455; called by muse, varscan2
- NR3C2 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 62/421 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs552665133, COSV60999332; called by muse, mutect2, varscan2
- OR10H2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 48/499 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs761078876; called by muse, mutect2, varscan2
- OR5AS1 | c.739G>C p.A247P | Missense Mutation (SNP) | VAF 32/656 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV57981287; called by muse, mutect2
- OR9G1 | c.906dup p.L303Tfs*35 | Frame Shift Ins (INS) | VAF 150/1342 reads (11%) | catalogued as rs1359495469; called by mutect2, varscan2
- PCDHB1 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 60/724 reads (8%) | catalogued as rs987038510, COSV100128058; called by muse, mutect2
- PCDHB3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 62/816 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1348193883, COSV50605938; called by muse, mutect2
- PDCD2L | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV55826088; called by muse, mutect2
- PHF14 | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 127/299 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV68856662; called by muse, mutect2, varscan2
- PRKCD | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 38/978 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as rs1477567912, COSV100388166; called by muse, mutect2
- PTPRC | c.3004G>A p.D1002N | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs1268528022, COSV61412119; called by muse, mutect2, varscan2
- RAB36 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 65/472 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs760314390; called by muse, mutect2, varscan2
- SIPA1L1 | c.3374G>A p.R1125Q | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs770442815, COSV62170433; called by muse, mutect2, varscan2
- SNX29 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 21/301 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1345403233; called by muse, mutect2
- SULT1E1 | c.854A>G p.E285G | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56948477; called by muse, mutect2, varscan2
- TAF1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV52119517; called by muse, mutect2, varscan2
- TATDN2 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 199/916 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.365); catalogued as COSV55052333; called by muse, mutect2, varscan2
- USH2A | c.9917G>T p.C3306F | Missense Mutation (SNP) | VAF 134/315 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56452187; called by muse, mutect2, varscan2
- ZNF772 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.968); catalogued as rs767521942, COSV100582741; called by muse, mutect2
- ABCA3 | c.2848C>T p.L950F | Missense Mutation (SNP) | VAF 16/550 reads (3%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- ALS2 | c.4504G>C p.D1502H | Missense Mutation (SNP) | VAF 21/506 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2
- AZI2 | c.687A>C p.E229D | Missense Mutation (SNP) | VAF 46/553 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- BLK | c.997T>A p.S333T | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HERPUD1 | c.722A>G p.N241S | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- IGLV3-1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 310/660 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRP2 | c.10292A>G p.E3431G | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC31 | c.790T>G p.C264G | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MAGEC1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 72/878 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); called by muse, mutect2
- MCOLN2 | c.1402A>T p.T468S | Missense Mutation (SNP) | VAF 52/442 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by mutect2, varscan2
- MPDZ | c.4886C>A p.T1629N | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRPL3 | c.112G>T p.V38F | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); called by mutect2, varscan2
- NDST3 | c.563T>A p.L188H | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NFKB2 | c.2189G>T p.G730V | Missense Mutation (SNP) | VAF 52/409 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- NT5C2 | c.633+1G>A p.X211_splice | Splice Site (SNP) | VAF 252/558 reads (45%) | called by muse, mutect2, varscan2
- OR5AS1 | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 31/650 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- OSBPL6 | c.888C>G p.D296E | Missense Mutation (SNP) | VAF 161/377 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PDZD2 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 74/797 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- PTPN21 | c.406A>C p.T136P | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PTPRQ | c.3343A>T p.S1115C (on ENST00000616559; = p.S1073C on NM_001145026.2) | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- PXDN | c.3976A>G p.N1326D | Missense Mutation (SNP) | VAF 140/267 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- RBPJL | c.1535A>G p.H512R | Missense Mutation (SNP) | VAF 264/522 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- RGS3 | c.219del p.W73Cfs*22 | Frame Shift Del (DEL) | VAF 32/240 reads (13%) | called by mutect2, varscan2
- SCPEP1 | c.188A>G p.K63R | Missense Mutation (SNP) | VAF 91/188 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SLC44A5 | c.53-2A>C p.X18_splice | Splice Site (SNP) | VAF 18/268 reads (7%) | called by muse, mutect2
- SP5 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 243/636 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SPTBN4 | c.3067C>T p.R1023C | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SUPT6H | c.4429C>A p.Q1477K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- TTN | c.60770A>G p.K20257R (on ENST00000591111; = p.K12833R on NM_003319.4) | Missense Mutation (SNP) | VAF 71/497 reads (14%) | PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- UBAP1L | c.923T>G p.L308R | Missense Mutation (SNP) | VAF 237/538 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBXN10 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 45/326 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AHNAK2 | c.13264C>T p.L4422= | Silent (SNP) | VAF 57/423 reads (13%) | called by muse, mutect2, varscan2
- ANKRD12 | c.3507C>T p.T1169= | Silent (SNP) | VAF 95/242 reads (39%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.9A>G p.L3= | Silent (SNP) | VAF 62/988 reads (6%) | called by muse, mutect2
- ASXL3 | c.2820C>T p.S940= | Silent (SNP) | VAF 36/354 reads (10%) | called by muse, mutect2, varscan2
- ATP13A4 | c.144G>A p.L48= | Silent (SNP) | VAF 123/427 reads (29%) | catalogued as rs1292266169; called by muse, mutect2, varscan2
- B4GALT7 | c.555G>T p.V185= | Silent (SNP) | VAF 48/890 reads (5%) | called by muse, mutect2
- CFAP47 | c.951G>A p.K317= | Silent (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- COL8A1 | c.927T>C p.P309= | Silent (SNP) | VAF 36/600 reads (6%) | catalogued as COSV53730030; called by muse, mutect2
- CPEB2 | c.537G>A p.R179= | Silent (SNP) | VAF 80/356 reads (22%) | catalogued as rs1273734193; called by muse, varscan2
- CUEDC2 | c.651G>T p.L217= | Silent (SNP) | VAF 66/180 reads (37%) | called by mutect2, varscan2
- HERC4 | c.1980A>G p.T660= (on ENST00000395198 / NM_022079.3; = p.T652= on NM_015601.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/124 reads (41%) | called by muse, mutect2, varscan2
- HRH3 | c.306C>T p.F102= | Silent (SNP) | VAF 20/193 reads (10%) | catalogued as rs201117959, COSV58048095; called by muse, mutect2, varscan2
- HS3ST1 | c.222C>T p.L74= | Silent (SNP) | VAF 46/703 reads (7%) | called by muse, mutect2
- IGLL5 | c.120C>T p.R40= | Silent (SNP) | VAF 63/136 reads (46%) | catalogued as rs755794558, COSV104440336, COSV73249987; called by muse, mutect2, varscan2
- ITGAM | c.1974C>G p.V658= (on ENST00000648685 / NM_001145808.2; = p.V657= on NM_000632.4) | Silent (SNP) | VAF 8/258 reads (3%) | catalogued as rs1162107162; called by muse, mutect2
- MBD3 | c.162C>T p.G54= | Silent (SNP) | VAF 281/456 reads (62%) | catalogued as rs767717405; called by muse, mutect2, varscan2
- MFHAS1 | c.2379G>C p.L793= | Silent (SNP) | VAF 12/322 reads (4%) | called by muse, mutect2
- NRP1 | c.2583C>T p.I861= | Silent (SNP) | VAF 300/689 reads (44%) | called by muse, mutect2, varscan2
- OR10W1 | c.591C>T p.A197= | Silent (SNP) | VAF 113/399 reads (28%) | catalogued as rs1040742907; called by muse, mutect2, varscan2
- PRDX2 | c.84G>A p.V28= | Silent (SNP) | VAF 98/1490 reads (7%) | called by muse, mutect2
- RPS6KL1 | c.36C>T p.P12= | Silent (SNP) | VAF 60/443 reads (14%) | catalogued as rs754869702, COSV63581401; called by muse, mutect2, varscan2
- SCGN | c.126C>T p.L42= | Silent (SNP) | VAF 85/177 reads (48%) | called by muse, mutect2, varscan2
- SHANK2 | c.1383G>A p.A461= | Silent (SNP) | VAF 32/518 reads (6%) | catalogued as rs782599530, COSV53607719; called by muse, mutect2
- STK32A | c.180G>A p.V60= | Silent (SNP) | VAF 15/406 reads (4%) | called by muse, mutect2
- TOR1A | c.114C>A p.I38= | Silent (SNP) | VAF 92/494 reads (19%) | called by muse, mutect2, varscan2
- VBP1 | c.270C>T p.Y90= | Silent (SNP) | VAF 29/219 reads (13%) | catalogued as rs1557310343; called by muse, mutect2, varscan2
- ZMYND12 | c.951C>T p.Y317= | Silent (SNP) | VAF 39/348 reads (11%) | called by muse, mutect2, varscan2
- AC073140.1 | n.88T>C | RNA (SNP) | VAF 12/171 reads (7%) | catalogued as rs1016657226; called by muse, mutect2
- ADA | c.679-25T>G | Intron (SNP) | VAF 65/540 reads (12%) | called by mutect2, varscan2
- AP001425.1 | chr21:38208316 C>A | 5'Flank (SNP) | VAF 142/452 reads (31%) | called by muse, mutect2, varscan2
- ARHGAP40 | chr20:38651026 G>T | 3'Flank (SNP) | VAF 8/41 reads (20%) | called by muse, varscan2
- BIRC2 | c.-54G>A | 5'UTR (SNP) | VAF 126/598 reads (21%) | called by muse, mutect2, varscan2
- BIRC6 | c.9981-32T>C | Intron (SNP) | VAF 20/67 reads (30%) | catalogued as rs764521349; called by muse, mutect2, varscan2
- BOK | c.*1364G>A | 3'UTR (SNP) | VAF 239/507 reads (47%) | called by muse, mutect2, varscan2
- BPNT2 | c.*4782T>A | 3'UTR (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2
- BRWD3 | c.*1525T>G | 3'UTR (SNP) | VAF 88/140 reads (63%) | called by muse, mutect2, varscan2
- C10orf95 | chr10:102454231 C>T | 5'Flank (SNP) | VAF 32/462 reads (7%) | called by muse, mutect2
- C2orf68 | c.*1793G>T | 3'UTR (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- C2orf68 | c.*1667G>C | 3'UTR (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- C2orf68 | c.*1040G>C | 3'UTR (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- C2orf68 | c.*613G>C | 3'UTR (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- C2orf68 | c.*272G>C | 3'UTR (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- C2orf81 | c.*100T>G | 3'UTR (SNP) | VAF 39/242 reads (16%) | catalogued as COSV99292398; called by muse, mutect2, varscan2
- CEP120 | c.*621A>G | 3'UTR (SNP) | VAF 53/206 reads (26%) | called by muse, mutect2, varscan2
- CPS1 | c.*267A>G | 3'UTR (SNP) | VAF 48/148 reads (32%) | called by muse, mutect2, varscan2
- CWH43 | c.43+222G>A | Intron (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- CYP4F24P | n.741G>A | RNA (SNP) | VAF 72/772 reads (9%) | catalogued as rs534394665; called by muse, mutect2
- DACH2 | c.1751-1368T>G | Intron (SNP) | VAF 54/92 reads (59%) | called by mutect2, varscan2
- DNAJC27 | c.*3249_*3285del | 3'UTR (DEL) | VAF 45/149 reads (30%) | called by mutect2, varscan2
- DRAM1 | c.*453dup | 3'UTR (INS) | VAF 29/112 reads (26%) | catalogued as rs991153371; called by mutect2, varscan2
- DUSP19 | c.*94C>T | 3'UTR (SNP) | VAF 15/318 reads (5%) | called by muse, mutect2
- ELOVL6 | c.*208C>T | 3'UTR (SNP) | VAF 29/460 reads (6%) | called by muse, mutect2
- EPPIN-WFDC6 | c.522+634G>C | Intron (SNP) | VAF 8/224 reads (4%) | called by muse, mutect2
- ERO1B | c.-106G>C | 5'UTR (SNP) | VAF 45/303 reads (15%) | called by muse, mutect2
- FSTL4 | c.*831T>C | 3'UTR (SNP) | VAF 42/646 reads (7%) | called by muse, mutect2
- GALNT17 | c.-450G>C | 5'UTR (SNP) | VAF 63/175 reads (36%) | called by muse, mutect2, varscan2
- GLRA4 | c.-351C>A | 5'UTR (SNP) | VAF 16/272 reads (6%) | called by muse, mutect2
- HLA-F-AS1 | n.1586G>A | RNA (SNP) | VAF 77/241 reads (32%) | called by muse, mutect2, varscan2
- IDH2 | c.*1099G>A | 3'UTR (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- IGF1R | c.-513G>A | 5'UTR (SNP) | VAF 38/432 reads (9%) | called by muse, mutect2
- IGF2 | chr11:2129174 C>A | 3'Flank (SNP) | VAF 54/303 reads (18%) | called by muse, mutect2, varscan2
- ITPKB | c.*2901G>C | 3'UTR (SNP) | VAF 20/330 reads (6%) | called by muse, mutect2
- KIRREL3 | c.1696+108C>A | Intron (SNP) | VAF 46/1404 reads (3%) | called by muse, mutect2
- KRBOX1 | c.-47+639G>T | Intron (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- KRIT1 | c.*1016C>T | 3'UTR (SNP) | VAF 12/100 reads (12%) | catalogued as rs530673335; called by muse, mutect2, varscan2
- LINC00431 | n.596G>A | RNA (SNP) | VAF 62/240 reads (26%) | called by muse, mutect2, varscan2
- MCOLN2 | c.*84C>G | 3'UTR (SNP) | VAF 296/447 reads (66%) | called by muse, mutect2, varscan2
- MEN1 | c.*457A>T | 3'UTR (SNP) | VAF 226/355 reads (64%) | called by mutect2, varscan2
- MGAT4EP | n.2524G>A | RNA (SNP) | VAF 16/193 reads (8%) | called by muse, mutect2
- MGLL | c.*1931A>C | 3'UTR (SNP) | VAF 27/380 reads (7%) | catalogued as rs781774464; called by muse, mutect2
- MMP16 | c.*1415T>A | 3'UTR (SNP) | VAF 13/270 reads (5%) | called by muse, mutect2
- MTR | c.*2127C>T | 3'UTR (SNP) | VAF 69/139 reads (50%) | called by muse, mutect2, varscan2
- NAALADL2 | c.-65C>T | 5'UTR (SNP) | VAF 496/878 reads (56%) | called by muse, mutect2, varscan2
- OBI1 | c.*1040A>T | 3'UTR (SNP) | VAF 122/388 reads (31%) | called by muse, mutect2, varscan2
- OPRD1 | c.*119G>A | 3'UTR (SNP) | VAF 11/260 reads (4%) | catalogued as rs1057381432; called by muse, mutect2
- OR2C3 | c.*341C>T | 3'UTR (SNP) | VAF 21/123 reads (17%) | catalogued as rs1212200297; called by muse, mutect2, varscan2
- OTULIN | c.-18T>C | 5'UTR (SNP) | VAF 60/203 reads (30%) | called by muse, mutect2, varscan2
- P3H2 | c.1453-94C>A | Intron (SNP) | VAF 51/78 reads (65%) | called by muse, mutect2, varscan2
- PCDH18 | c.-399A>G | 5'UTR (SNP) | VAF 32/186 reads (17%) | called by muse, mutect2, varscan2
- PCOLCE | c.463+325C>T | Intron (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- PDLIM5 | c.*1519C>T | 3'UTR (SNP) | VAF 20/175 reads (11%) | called by muse, mutect2, varscan2
- PEX2 | c.-242G>C | 5'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- PHF13 | c.*656G>A | 3'UTR (SNP) | VAF 138/441 reads (31%) | called by muse, mutect2, varscan2
- PHOSPHO1 | c.*513G>A | 3'UTR (SNP) | VAF 18/498 reads (4%) | catalogued as rs1358596179; called by muse, mutect2
- POLR1B | c.177+65G>A | Intron (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- PRLR | c.*1699A>G | 3'UTR (SNP) | VAF 34/356 reads (10%) | called by muse, mutect2
- PRR32 | c.*33G>A | 3'UTR (SNP) | VAF 40/1192 reads (3%) | called by muse, mutect2
- RBM7 | c.439-580A>G | Intron (SNP) | VAF 8/25 reads (32%) | catalogued as rs962976103; called by muse, mutect2, varscan2
- RNF145 | c.*531G>A | 3'UTR (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- SGK1 | c.285+41T>A | Intron (SNP) | VAF 149/179 reads (83%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.-117C>T | 5'UTR (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- SHMT2 | c.*341T>C | 3'UTR (SNP) | VAF 32/249 reads (13%) | called by muse, mutect2, varscan2
- SOWAHA | c.*545T>C | 3'UTR (SNP) | VAF 62/212 reads (29%) | called by muse, mutect2, varscan2
- SPAST | c.*1367A>T | 3'UTR (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- SPATA8 | n.589C>A | RNA (SNP) | VAF 244/431 reads (57%) | called by muse, mutect2, varscan2
- SRP68 | c.*448C>T | 3'UTR (SNP) | VAF 20/452 reads (4%) | catalogued as rs975654646; called by muse, mutect2
- SYNCRIP | c.*339A>C | 3'UTR (SNP) | VAF 47/319 reads (15%) | called by muse, mutect2, varscan2
- SYNPR | c.-94C>T | 5'UTR (SNP) | VAF 15/310 reads (5%) | called by muse, mutect2
- TFAM | c.-79A>G | 5'UTR (SNP) | VAF 88/419 reads (21%) | called by muse, mutect2, varscan2
- TMEM245 | c.*5249A>C | 3'UTR (SNP) | VAF 114/227 reads (50%) | called by muse, mutect2, varscan2
- UBAP2 | c.*268G>A | 3'UTR (SNP) | VAF 77/297 reads (26%) | called by muse, mutect2, varscan2
- UGT2A1 | c.*204C>G | 3'UTR (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2, varscan2
- VSX2 | c.*9G>A | 3'UTR (SNP) | VAF 51/117 reads (44%) | catalogued as rs549537406, COSV56218014; called by muse, mutect2, varscan2
- WDR72 | c.*2240A>G | 3'UTR (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- XIRP2 | c.*803G>A | 3'UTR (SNP) | VAF 50/157 reads (32%) | called by muse, mutect2, varscan2
- YIPF5 | c.*1146T>A | 3'UTR (SNP) | VAF 41/174 reads (24%) | called by muse, mutect2, varscan2
- ZNF512B | c.*910C>T | 3'UTR (SNP) | VAF 18/538 reads (3%) | catalogued as rs1029704429; called by muse, mutect2
- ZNF624 | c.*299T>C | 3'UTR (SNP) | VAF 27/171 reads (16%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.-109C>T | 5'UTR (SNP) | VAF 12/290 reads (4%) | called by muse, mutect2
